Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A65M, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A65M-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN THIRTEEN (13) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN SEVENTEEN (17) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE # DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 3 = 6 WITH TERTIARY GLEASON PATTERN 4.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.7 CM.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 MX.
- K. TNM HISTOLOGIC GRADE = G3.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 6.9
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 3
GLEASON SUM SCORE: 6
GLEASON 4/5 PERCENTAGE: 10%
WEIGHT OF PROSTATE: 58.45gm
TUMOR SIZE: Maximum dimension: 1.7 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 30
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2c
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G2, Moderately differentiated

ICD-O-3
Adenocarcinoma, acinar
path
Adenocarcinoma NOS
8/40/13
Site: Prostate NOS C61.9
JW 5/16/13

PATIENT HISTORY:

The patient is a -year-old black male with a history of PSA value of 6.9. The patient also has a history of biopsy on this biopsy reveals: Poorly-differentiated prostatic adenocarcinoma, Gleason score 3+4 = 7 in the right side of the prostate and moderately-differentiated prostatic adenocarcinoma, Gleason score 3+3 = 6 in the left side of the prostate. The patient also has a history of a benign right breast mass with recurrence and a right femur fracture.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

Source: NCI Genomic Data Commons file 95eb1dcf-a0b0-43e6-a1e5-0c18dfca7661 (TCGA-EJ-A65M.E0FB271C-8BC6-43FB-BE90-85A28009D962.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).